MMRF case MMRF_1652 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3ec5b04e-4677-4573-b907-e386b84ab39d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,069 days); ISS stage: II; Days to last known disease status: 1,147 days (3.1 years); Days to last follow up: 1,147 days (3.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 140 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 142 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1280 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.522 mg/dL; Immunoglobulin G 56.7 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 5.1 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.74 ×10⁹/L; Platelets 496 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Total Protein 11.2 g/dL; Glucose 6.05 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 64 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.841 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.63 ×10⁹/L; Platelets 506 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 159: M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.114 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 5.28 mmol/L.
- Day 260 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 356 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.875 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.213 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.53 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.94 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.171 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 3.2 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.93 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.862 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 2.75 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 5.67 mmol/L.
- Day 706 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.709 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 3.61 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.24 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.78 mmol/L.
- Day 790 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.95 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 902 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 5.39 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.34 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 993 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.29 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.67 mmol/L.
- Day 1,091 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 6.08 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 1,147 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -20: Weight: 80 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1652_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1652_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
